Somatic mutation profile of tumor specimen MMRF_1179_2_BM_CD138pos (aliquot MMRF_1179_2_BM_CD138pos_T1_KHS5U_L12890) from MMRF case MMRF_1179, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.4 years (29,365 days).
Specimen MMRF_1179_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfc25a5c-19ed-46da-84b9-6504e68a1ced.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1179_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1179_1_PB_Whole_C1_KHS5U_L13430; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8a7ba1-c7da-4c82-b2f3-83ceb61831fe

The open-access MAF lists 118 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 25, Intron 20, Silent 14, 5'UTR 4, Frame Shift Del 3, RNA 3, Nonsense Mutation 2, Splice Site 2, 3'Flank 2, IGR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.9656A>G p.H3219R | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1296869293, COSV56529774; called by muse, mutect2, varscan2
- CNTNAP3B | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298872013; called by muse, mutect2, varscan2
- GMIP | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs759085807; called by muse, mutect2, varscan2
- HLA-G | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 87/164 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.603); catalogued as rs796748483; called by muse, mutect2, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, varscan2
- IGLV3-1 | c.277A>T p.I93F | Missense Mutation (SNP) | VAF 106/202 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs548457166; called by muse, varscan2
- IRF8 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV51896682; called by muse, mutect2, varscan2
- KIAA1549 | c.5810G>A p.R1937Q (on ENST00000422774 / NM_001164665.2; = p.R1921Q on NM_020910.3) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572566754, COSV99650560; called by muse, mutect2, varscan2
- METTL21A | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs554301793; called by muse, mutect2, varscan2
- MSH4 | c.2583del p.K862Rfs*30 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as COSV54196091; called by mutect2, pindel, varscan2
- PUM2 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs779614613; called by muse, mutect2, varscan2
- SLC4A1 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761704181; called by muse, mutect2
- UGGT1 | c.4654C>T p.R1552C | Missense Mutation (SNP) | VAF 124/267 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1001527546, COSV52134246; called by muse, mutect2, varscan2
- AASDH | c.2860G>A p.G954S | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30A | c.3880C>G p.Q1294E (on ENST00000611781; = p.Q1238E on NM_052997.2) | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- APOB | c.9022G>T p.A3008S | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- BPIFA3 | c.623dup p.C209Mfs*6 | Frame Shift Ins (INS) | VAF 64/174 reads (37%) | called by mutect2, pindel, varscan2
- CCDC88A | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 159/366 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CLCN6 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- COL14A1 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBG3 | c.6910G>A p.E2304K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DCLK2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX60 | c.2024G>A p.R675K | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DRD5 | c.584A>C p.N195T | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HDAC4 | c.3082_3104del p.W1028Lfs*40 | Frame Shift Del (DEL) | VAF 55/156 reads (35%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.53T>A p.L18* | Nonsense Mutation (SNP) | VAF 36/41 reads (88%) | called by muse, varscan2
- IRF2BP2 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 205/410 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITPR1 | c.5497G>T p.E1833* (on ENST00000354582; = p.E1778* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- JAML | c.728T>A p.F243Y (on ENST00000356289 / NM_001098526.2; = p.F233Y on NM_153206.3) | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KIF3C | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- L3MBTL3 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 116/244 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIMD2 | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRPPRC | c.2365T>G p.F789V | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- MYO18A | c.5719G>A p.D1907N | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NCKAP5L | c.168G>C p.E56D | Missense Mutation (SNP) | VAF 72/73 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PATL1 | c.1486A>G p.M496V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PITX3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 66/139 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PREX1 | c.2681A>G p.D894G | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPL24 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1389-3C>T | Splice Region (SNP) | VAF 83/191 reads (43%) | called by muse, mutect2, varscan2
- SNAP91 | c.*10+2T>G | Splice Site (SNP) | VAF 109/233 reads (47%) | called by muse, mutect2, varscan2
- TACC2 | c.7157A>G p.K2386R (on ENST00000334433; = p.K464R on NM_006997.4) | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TBC1D22B | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.94271_94281del p.E31424Vfs*2 (on ENST00000591111; = p.E24000Vfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 122/358 reads (34%) | called by pindel, varscan2
- TUSC3 | c.367T>A p.C123S | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WWC3 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 96/103 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZFP62 | c.1877T>G p.F626C (on ENST00000502412 / NM_001377944.1; = p.F593C on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZSCAN16 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf95 | c.945C>T p.S315= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs914415235; called by muse, mutect2
- CAB39 | c.942G>A p.T314= | Silent (SNP) | VAF 105/221 reads (48%) | catalogued as rs146490647; called by muse, mutect2, varscan2
- CD177 | c.162G>T p.G54= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- CDON | c.774C>T p.D258= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as rs777623487; called by muse, mutect2, varscan2
- CH25H | c.606C>A p.T202= | Silent (SNP) | VAF 86/168 reads (51%) | called by muse, mutect2, varscan2
- CLK4 | c.486G>A p.V162= | Silent (SNP) | VAF 8/230 reads (3%) | called by muse, mutect2
- DOCK6 | c.4437G>A p.T1479= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs1433085969; called by muse, mutect2, varscan2
- DOCK8 | c.4758C>T p.A1586= | Silent (SNP) | VAF 130/306 reads (42%) | called by muse, mutect2, varscan2
- LIMD2 | c.234C>T p.S78= | Silent (SNP) | VAF 56/115 reads (49%) | catalogued as rs1380154462; called by muse, mutect2, varscan2
- MMP1 | c.813C>G p.G271= | Silent (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2, varscan2
- NOS3 | c.3552G>A p.Q1184= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as COSV52491608; called by muse, mutect2, varscan2
- NR4A3 | c.483C>A p.P161= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1518G>A p.L506= | Silent (SNP) | VAF 81/135 reads (60%) | called by muse, mutect2, varscan2
- TNKS1BP1 | c.528T>G p.L176= | Silent (SNP) | VAF 73/165 reads (44%) | called by muse, mutect2, varscan2
- AC011487.1 | n.133G>C | RNA (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- ADGRG2 | c.263-44del | Intron (DEL) | VAF 16/24 reads (67%) | called by mutect2, pindel, varscan2
- ANAPC4 | c.1623+114C>T | Intron (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- AOPEP | c.797+2590C>A | Intron (SNP) | VAF 98/222 reads (44%) | called by muse, mutect2, varscan2
- ARID4A | c.*981C>G | 3'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- ATP13A5 | c.*27C>G | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- CCDC6 | c.*2453G>T | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- CCN6 | c.346+49A>T | Intron (SNP) | VAF 22/44 reads (50%) | catalogued as rs1168774569; called by muse, varscan2
- CFAP298-TCP10L | c.-307C>T | 5'UTR (SNP) | VAF 104/237 reads (44%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.801G>A | RNA (SNP) | VAF 19/160 reads (12%) | catalogued as rs1414224469; called by mutect2, varscan2
- CRB1 | c.4005+1344C>T | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.*1296A>G | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- DCAF13 | c.624+1019G>A | Intron (SNP) | VAF 80/164 reads (49%) | catalogued as rs201666891; called by muse, mutect2, varscan2
- DCK | c.91+67C>T | Intron (SNP) | VAF 15/118 reads (13%) | catalogued as rs772840327; called by muse, mutect2, varscan2
- EFCC1 | c.*286C>A | 3'UTR (SNP) | VAF 176/383 reads (46%) | catalogued as COSV71401990; called by muse, mutect2, varscan2
- EFNB2 | c.*1210A>C | 3'UTR (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- GLRB | c.*1010G>C | 3'UTR (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- GTF3C3 | c.1390+335A>G | Intron (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- HMX2 | c.*318A>G | 3'UTR (SNP) | VAF 35/82 reads (43%) | catalogued as rs1316072893; called by muse, mutect2, varscan2
- HTR3E | c.*299G>C | 3'UTR (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.113C>T | RNA (SNP) | VAF 96/185 reads (52%) | called by muse, mutect2, varscan2
- ITK | c.*2221C>T | 3'UTR (SNP) | VAF 52/91 reads (57%) | called by muse, mutect2, varscan2
- KRI1 | c.*168G>A | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- LRAT | c.*1827A>T | 3'UTR (SNP) | VAF 66/136 reads (49%) | called by muse, mutect2, varscan2
- LTB | c.163-32G>A | Intron (SNP) | VAF 251/505 reads (50%) | catalogued as rs773170624; called by muse, mutect2, varscan2
- LYPLAL1 | c.*883T>G | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*3783C>A | 3'UTR (SNP) | VAF 62/122 reads (51%) | called by muse, mutect2, varscan2
- MOB2 | chr11:1469956 C>A | 3'Flank (SNP) | VAF 30/215 reads (14%) | called by muse, mutect2, varscan2
- MUSK | c.-87C>T | 5'UTR (SNP) | VAF 188/380 reads (49%) | called by muse, mutect2, varscan2
- NAA20 | c.-32G>C | 5'UTR (SNP) | VAF 78/163 reads (48%) | catalogued as rs909220641; called by muse, mutect2, varscan2
- NEDD4 | c.*2697A>C | 3'UTR (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- NTNG1 | c.1087+927dup | Intron (INS) | VAF 30/68 reads (44%) | called by pindel, varscan2
- PDPK1 | c.25-439A>G | Intron (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- PHB2 | c.789+13G>C | Intron (SNP) | VAF 18/19 reads (95%) | called by muse, varscan2
- PLAAT3 | c.-199G>A | 5'UTR (SNP) | VAF 81/154 reads (53%) | called by muse, mutect2, varscan2
- POLR3A | c.*1397dup | 3'UTR (INS) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- PPP2R5C | c.93+23185A>G | Intron (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PPP3CB | c.*1069C>T | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- PPP4R2 | c.*1455A>T | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- RALB | c.*666T>C | 3'UTR (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- RPLP2 | c.124-68C>G | Intron (SNP) | VAF 17/29 reads (59%) | called by mutect2, varscan2
- SEMA5A | c.*2579T>C | 3'UTR (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- SHOX2 | c.347-1005G>A | Intron (SNP) | VAF 52/115 reads (45%) | called by muse, mutect2, varscan2
- STAMBP | c.*3887T>G | 3'UTR (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- STAT5A | c.2062+28C>T | Intron (SNP) | VAF 54/104 reads (52%) | called by muse, mutect2, varscan2
- SZT2 | c.10087-139A>T | Intron (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2
- TEX35 | c.90+102G>A | Intron (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- TMEM175 | c.192+120A>G | Intron (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- TOX2 | c.*389_*393del | 3'UTR (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- TP53 | c.-29+1111C>T | Intron (SNP) | VAF 15/15 reads (100%) | called by muse, mutect2, varscan2
- TP53INP1 | c.*868C>T | 3'UTR (SNP) | VAF 44/80 reads (55%) | called by muse, mutect2, varscan2
- TRAPPC6B | c.*714C>A | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- Unknown | chr2:111238429 C>T | IGR (SNP) | VAF 83/159 reads (52%) | called by muse, mutect2, varscan2
- WDR17 | chr4:176181887 T>C | 3'Flank (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- WDR7 | c.*901C>T | 3'UTR (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
